Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3SB, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3SB-01A (Primary Tumor).

- LAB RESULTS

		hw 3/30/12

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

1st Specimen collected on ()
Accessioned on ()

FINAL DIAGNOSIS ----- Pathologist: ()

1) LYMPH NODE, RIGHT PARATRACHEAL (EXCISION): METASTATIC PAPILLARY THYROID CARCINOMA IN ONE (1) LYMPH NODE.

2) LYMPH NODE, LEFT PARATRACHEAL (EXCISION): TWO LYMPH NODES NEGATIVE FOR TUMOR.

3) LEFT SUPERIOR PARATHYROID (EXCISION): SMALL FRAGMENT OF PARATHYROID TISSUE (<1 MG).

4) PARATHYROID RIGHT INFERIOR (EXCISION): PARATHYROID TISSUE (4 MG).

5) THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 2.0 cm

FOCALITY:

Unifocal

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in 2 of 14 lymph nodes. No extra nodal extension identified.

EXTENT OF INVASION (STAGING) PRIMARY TUMOR:

PT3: Tumor with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI paratracheal nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Mild thyroiditis

6) LYMPH NODE DISSECTION, LEFT PARATRACHEAL (EXCISION): METASTATIC PAPILLARY THYROID CARCINOMA IN ONE (1) OF EIGHT (8) LYMPH NODES.

Reported by:

Final Report Signed on ()

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

5-112
RD

Source: NCI Genomic Data Commons file db653b89-3783-43b9-8329-71b2f513860b (TCGA-FK-A3SB.E4786207-1ECD-48F6-BDC0-C4C27209D926.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).